Surgical pathology report (de-identified scan), TCGA case TCGA-E8-A433, project TCGA-THCA (Thyroid Carcinoma), tissue source site Asterand, specimen TCGA-E8-A433-01A (Primary Tumor).

Procurement Date: Laterality: Papillary carcinoma

Path Report: Tumor type:

Papillary carcinoma

Tumor size:

2.5 x 2 x 2

Laterality:

Right

Focality:

Unifocal

Extrathyroidal extension:

No

Markers and special stains:

Additional comments: Lymphocyte invasion - present

ICD-O-3

carcinoma, papillary, thyroid
8260/3

Site: thyroid, NOS

C73.9

8-3-12
EP

Source: NCI Genomic Data Commons file 9291933e-3125-4548-a926-1303a449edd1 (TCGA-E8-A433.A87AB565-515E-4DF2-BC2A-5420AB808377.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).